MMRF case MMRF_2317 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/f40a4d88-770b-4fd7-83c4-5809ebe17512

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 75 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 75.6 years (27,609 days); ISS stage: I; Days to last known disease status: 610 days (1.7 years); Days to last follow up: 610 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 338 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 319 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 610 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 2.01 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.9 mg/dL; Immunoglobulin G 7.17 g/L; Immunoglobulin A 20.9 g/L; Immunoglobulin M 0.31 g/L; Beta 2 Microglobulin 2.33 µg/mL; Lactate Dehydrogenase 5.3 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 6.36 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 327 ×10⁹/L; Creatinine 68.1 µmol/L; Calcium 2.6 mmol/L; Albumin 41 g/L; Total Protein 7.5 g/dL; Glucose 6 mmol/L.
- Day 108 (ECOG 1): M Protein 1.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.28 mg/dL; Immunoglobulin G 8.72 g/L; Immunoglobulin A 7.28 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 6.32 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 13.9 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 498 ×10⁹/L; Creatinine 76.9 µmol/L; Calcium 2.55 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 7.15 mmol/L.
- Day 204: M Protein 1.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 8.79 mg/dL; Immunoglobulin G 7.47 g/L; Immunoglobulin A 5.55 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 6.35 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.85 ×10⁹/L; Absolute Neutrophil 2.41 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 97.2 µmol/L; Calcium 2.6 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.
- Day 281 (ECOG 0): M Protein 1.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.4 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 5.01 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 6.5 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.33 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 85.7 µmol/L; Calcium 2.53 mmol/L; Albumin 42 g/L; Total Protein 6.87 g/dL; Glucose 6.22 mmol/L.
- Day 367: M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15 mg/dL; Immunoglobulin G 8.43 g/L; Immunoglobulin A 4.97 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.14 µg/mL; Lactate Dehydrogenase 6.22 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 5.39 ×10⁹/L; Absolute Neutrophil 3.47 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 94.6 µmol/L; Calcium 2.63 mmol/L; Albumin 46 g/L; Total Protein 7.22 g/dL; Glucose 6.33 mmol/L.
- Day 428: M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.5 mg/dL; Immunoglobulin A 4.65 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.33 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 7.27 ×10⁹/L; Absolute Neutrophil 4.71 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 78.7 µmol/L; Calcium 2.55 mmol/L; Albumin 42 g/L; Total Protein 6.91 g/dL; Glucose 7.37 mmol/L.
- Day 540: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 23.9 mg/dL; Immunoglobulin G 8.84 g/L; Immunoglobulin A 5.19 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2.37 µg/mL; Lactate Dehydrogenase 5.65 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.72 ×10⁹/L; Absolute Neutrophil 3.49 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 105 µmol/L; Calcium 2.63 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 6.6 mmol/L.
- Day 610: M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.8 mg/dL; Immunoglobulin G 8.21 g/L; Immunoglobulin A 4.69 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 5.45 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.94 ×10⁹/L; Absolute Neutrophil 2.87 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.65 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2317_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2317_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
